Somatic mutation profile of tumor specimen TCGA-IB-AAUR-01A (aliquot TCGA-IB-AAUR-01A-21D-A38G-08) from TCGA case TCGA-IB-AAUR, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 67.3 years (24,576 days).
Specimen TCGA-IB-AAUR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e217f90c-d3c4-4f5d-b956-0b9e527affb8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-AAUR-10A (Blood Derived Normal), aliquot TCGA-IB-AAUR-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2fc837e8-d7ba-439c-9dae-e4b40a109de5

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.1064A>G p.D355G | Missense Mutation (SNP) | VAF 18/462 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61684573, COSV61686129, COSV61697475; called by muse, mutect2
- BPTF | c.2094T>C p.A698= | Silent (SNP) | VAF 21/614 reads (3%) | catalogued as COSV100076177; called by muse, mutect2
- GATAD2B | c.30C>T p.R10= | Silent (SNP) | VAF 39/603 reads (6%) | catalogued as COSV100898045; called by muse, mutect2
- INMT | c.564G>A p.K188= | Silent (SNP) | VAF 13/400 reads (3%) | catalogued as COSV99185177; called by muse, mutect2
